Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3811, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3811-01A (Primary Tumor).

Diagnosis

This concerns an invasive, poorly differentiated colic adenocarcinoma with partial neuroendocrine differentiation (G3), with penetration of all wall layers (pT3), with vascular invasion (L1, V1), with five lymph node metastases (5 of 15) and free resection margins as well as chronic appendicitis and free ligature area.

Source: NCI Genomic Data Commons file cd74fc0c-e885-47be-a1d4-c64deacfc796 (TCGA-AA-3811.93E283A7-47DA-4EC0-ABA3-B63B20565EF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).